Somatic mutation profile of tumor specimen 0DPHT7 from CCDI case PBCDLF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 12.6 years (4,615 days).
Specimen 0DPHT7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb2430d1-a330-4e5b-8048-dbfc27d6026a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPHSX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7eb4285-e94d-43e8-a419-aa91ff33e8f4

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Frame Shift Del 2, Intron 1, 3'UTR 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1 | c.1514C>A p.P505Q | Missense Mutation (SNP) | VAF 215/514 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV61797575; called by muse, mutect2, varscan2
- BPIFB3 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs747168207, COSV64957637, COSV64958364; called by muse, mutect2, varscan2
- COIL | c.192del p.L65Sfs*11 | Frame Shift Del (DEL) | VAF 58/165 reads (35%) | catalogued as rs763239843; called by mutect2, varscan2
- LRP2 | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 254/623 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs763132620, COSV55556541; called by muse, mutect2, varscan2
- MARCO | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 242/722 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as COSV100503163; called by muse, mutect2, varscan2
- PCDHA1 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs1554118039, COSV65374686; called by muse, mutect2, varscan2
- PHIP | c.3260G>A p.S1087N | Missense Mutation (SNP) | VAF 50/900 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as rs760760644; called by muse, mutect2
- USP17L18 | c.1212del p.K404Nfs*31 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs1560541801, COSV101543610; called by mutect2, varscan2
- ADCY5 | c.1324A>G p.M442V | Missense Mutation (SNP) | VAF 274/715 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PAX5 | c.295dup p.I99Nfs*3 | Frame Shift Ins (INS) | VAF 219/282 reads (78%) | called by mutect2, varscan2
- NUP98 | c.2166A>C p.I722= | Silent (SNP) | VAF 198/479 reads (41%) | called by muse, mutect2, varscan2
- OSR1 | c.381G>A p.T127= | Silent (SNP) | VAF 142/293 reads (48%) | catalogued as rs554346185; called by muse, mutect2, varscan2
- TUBB6 | c.202T>C p.L68= | Silent (SNP) | VAF 79/211 reads (37%) | called by muse, mutect2, varscan2
- UQCRC2 | c.822A>G p.E274= | Silent (SNP) | VAF 227/599 reads (38%) | called by muse, mutect2, varscan2
- ANLN | c.*99C>T | 3'UTR (SNP) | VAF 50/107 reads (47%) | catalogued as COSV56080974; called by muse, mutect2, varscan2
- KREMEN1 | chr22:29073100 G>C | 5'Flank (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- PATJ | c.5378+5033G>C | Intron (SNP) | VAF 239/632 reads (38%) | catalogued as rs1223427527; called by muse, mutect2, varscan2
